Somatic mutation profile of tumor specimen BA2541D (aliquot aq-BA2541D) from BEATAML1.0 case 2484, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 39.1 years (14,269 days).
Specimen BA2541D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d492398a-e8dd-417d-8b06-d4f6c489c26f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2259D (Solid Tissue Normal), aliquot aq-BA2259D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c6d8d5d-60cd-45c7-b2a7-e37634936176

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACMSD | c.264C>A p.D88E | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.046); called by muse, mutect2
- ARL6IP5 | c.535C>A p.L179I | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- ARPP21 | c.2030C>A p.A677E | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.381); called by muse, mutect2
- ELK3 | c.1113C>A p.S371R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2
- UBXN7 | c.830G>T p.R277L | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); called by muse, mutect2
